Somatic mutation profile of tumor specimen MP2PRT-PAUBNT-TMP1-A (aliquot MP2PRT-PAUBNT-TMP1-A-1-0-D-A818-36) from MP2PRT case MP2PRT-PAUBNT, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 3.7 years (1,343 days).
Specimen MP2PRT-PAUBNT-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 796856f4-8107-43b5-8939-5d3cc7d55cd5.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAUBNT-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAUBNT-NB1-A-1-0-D-A818-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/60db0d1a-1bed-454d-b19f-7569813a16ad

The open-access MAF lists 13 somatic variants for this specimen: 11 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 8, Silent 2, Nonsense Mutation 2, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 97/248 reads (39%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.339); catalogued as rs121913237, COSV54736383, COSV54736555, COSV54736974; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- DNAH9 | c.70C>T p.R24* | Nonsense Mutation (SNP) | VAF 97/524 reads (19%) | catalogued as COSV52352465; called by muse, mutect2, varscan2
- EIF5A2 | c.194C>T p.T65M | Missense Mutation (SNP) | VAF 27/110 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.005); catalogued as rs750910672; called by muse, mutect2, varscan2
- HPSE2 | c.1259G>A p.R420Q | Missense Mutation (SNP) | VAF 136/314 reads (43%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.978); catalogued as rs1414416508, COSV65182138; called by muse, mutect2, varscan2
- MAGEB6B | c.304G>A p.V102I | Missense Mutation (SNP) | VAF 120/148 reads (81%) | SIFT tolerated (0.49); PolyPhen benign (0.006); catalogued as rs777950806, COSV69689790; called by muse, mutect2, varscan2
- P2RX6 | c.118G>A p.A40T | Missense Mutation (SNP) | VAF 154/370 reads (42%) | SIFT tolerated (0.12); PolyPhen benign (0.005); catalogued as rs765463729, COSV53036810; called by muse, mutect2, varscan2
- PUDP | c.668G>A p.G223D | Missense Mutation (SNP) | VAF 129/143 reads (90%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.933); catalogued as COSV66906129; called by muse, varscan2
- TRIM60 | c.1045C>T p.R349* | Nonsense Mutation (SNP) | VAF 169/368 reads (46%) | catalogued as rs368275126; called by muse, mutect2, varscan2
- HNRNPAB | c.20_24delinsGAGACGACGGGCGCCA p.E7Gfs*75 | Frame Shift Ins (INS) | VAF 111/298 reads (37%) | called by muse*, pindel
- HOXD12 | c.330G>T p.E110D | Missense Mutation (SNP) | VAF 86/540 reads (16%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- LRRIQ1 | c.4086T>A p.H1362Q | Missense Mutation (SNP) | VAF 134/304 reads (44%) | SIFT tolerated (0.07); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- THUMPD2 | c.1248T>G p.L416= | Silent (SNP) | VAF 136/331 reads (41%) | catalogued as rs766395792; called by muse, mutect2, varscan2
- ZNF891 | c.318A>G p.R106= | Silent (SNP) | VAF 94/218 reads (43%) | called by muse, mutect2, varscan2
